TCGA case TCGA-DM-A288 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Colon; Tissue source site: University Of Michigan. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/143f2dd6-a280-41c5-9242-442ef91b73ec

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Israel; Age at index: 68 years; Vital status: Dead; Days to death: 427 days (1.2 years).

Diagnoses (2)
1. Mucinous adenocarcinoma (the primary disease): ICD-O-3 morphology code: 8480/3; ICD-10 code: C18.0; Tissue or organ of origin: Cecum; Site of resection or biopsy: Cecum; Classification of tumor: primary; Age at diagnosis: 68.7 years (25,084 days); Year of diagnosis: 2001; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIC; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 4; Lymph nodes tested: 22; Lymphatic invasion present: No; Vascular invasion present: No.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 69.6 years (25,404 days); Days to diagnosis: 320 days; Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Surgery, NOS.

Follow-up (2 entries)
- Day 320 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 320 days.
- Follow-up contact recording only the day: day 427.

Molecular and laboratory tests
- KRAS mutation, nos: Positive; Mutation codon: 13.
- Microsatellite Instability: Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 85 kg; Height: 170 cm; BMI: 29.4.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DM-A288-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 120 mg.
  Slide TCGA-DM-A288-01A-01-TSA: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 20; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DM-A288-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DM-A288-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Colon Mucinous Adenocarcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Lymph nodes examined: Yes; Lymphovascular invasion indicator: No; Microsatellite instability: No; Loci tested count: 6; Loci abnormal count: 0; KRAS gene analysis indicator: Yes; KRAS mutation found: Yes; BRAF gene analysis indicator: No; History colon polyps: No.
- Follow-up form 1: New tumor event diagnosis indicator: Yes.
- Follow-up form 1, New tumor event: New tumor event surgery: No; New tumor event radiation treatment: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 427 days; disease-specific survival: event status not recorded, 427 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 320 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DM-A288-01A-11D-A16U-01): tumor purity 0.83, ploidy 3.31, whole-genome doublings 1.
